Somatic mutation profile of tumor specimen TCGA-L5-A88Y-01A (aliquot TCGA-L5-A88Y-01A-11D-A351-09) from TCGA case TCGA-L5-A88Y, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 76.8 years (28,061 days).
Specimen TCGA-L5-A88Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf4caa1-272c-4874-ac3e-a5ab12029c90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A88Y-11A (Solid Tissue Normal), aliquot TCGA-L5-A88Y-11A-11D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3932fca2-6b7e-4a48-bb6b-38c6b7c61f59

The open-access MAF lists 217 somatic variants for this specimen: 172 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 40, Nonsense Mutation 8, Frame Shift Del 3, Intron 2, In Frame Del 2, Splice Region 1, Splice Site 1, 3'UTR 1, RNA 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOX9 | c.522C>A p.Y174* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as rs373719106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.3470G>T p.R1157M | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100623427; called by muse, mutect2
- AFF2 | c.1925A>C p.E642A | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.455); catalogued as COSV99664179; called by muse, mutect2, varscan2
- AMY2A | c.239T>G p.V80G | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV70214956; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752034399; called by muse, mutect2, varscan2
- APOBR | c.2701G>A p.E901K (on ENST00000431282; = p.E910K on NM_018690.4) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100112981; called by muse, mutect2
- ASH1L | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs761316149; called by muse, mutect2, varscan2
- ATF6 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1427354452; called by muse, mutect2, varscan2
- CACNA2D4 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.965); catalogued as rs758719842; called by muse, mutect2, varscan2
- CFHR5 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs747163679, COSV104375906, COSV56820416; called by muse, mutect2, varscan2
- CLSTN2 | c.2032A>T p.K678* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101515692; called by muse, mutect2, varscan2
- COL11A1 | c.5125A>C p.N1709H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62177442; called by muse, mutect2
- CPLANE1 | c.8303G>A p.R2768H | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752905880, COSV57070112; called by muse, mutect2, varscan2
- CPNE4 | c.607T>G p.L203V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101456769; called by muse, mutect2, varscan2
- CYLD | c.1807T>G p.L603V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61096473; called by muse, mutect2, varscan2
- CYP39A1 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 99/145 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs140524444; called by muse, mutect2, varscan2
- DCC | c.4015A>C p.T1339P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV71434255, COSV71438899; called by muse, mutect2, varscan2
- DNPEP | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771612801; called by muse, mutect2, varscan2
- DSEL | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.547); catalogued as COSV59490203; called by muse, mutect2, varscan2
- EPB41L3 | c.1390T>G p.L464V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV59453569, COSV59462802; called by muse, mutect2, varscan2
- EPHA6 | c.1799A>C p.K600T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs772090009, COSV101060733, COSV67561345; called by muse, mutect2, varscan2
- EVC | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs777256784, COSV53835800; called by muse, mutect2, varscan2
- FAM135B | c.3097T>G p.L1033V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV52738518; called by muse, mutect2, varscan2
- FAM135B | c.1682A>C p.K561T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as rs368544496; called by muse, mutect2
- FAM171B | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as rs907374321; called by mutect2, varscan2
- FCRL1 | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63826081, COSV63826278; called by muse, mutect2, varscan2
- FIGN | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV60772298, COSV60772349; called by muse, mutect2, varscan2
- GABRA6 | c.487T>G p.F163V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50883052; called by muse, mutect2, varscan2
- GRIA1 | c.2480A>C p.E827A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99598244; called by muse, mutect2, varscan2
- GRIK4 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); catalogued as rs373728384; called by muse, varscan2
- GUCY1A1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.567); catalogued as COSV56649561; called by muse, mutect2, varscan2
- HTR5A | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV55283846; called by muse, mutect2, varscan2
- IQCA1 | c.2133C>T p.Y711= | Splice Region (SNP) | VAF 7/48 reads (15%) | catalogued as rs779686716; called by muse, mutect2
- ITIH6 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1379958504, COSV54494808; called by muse, mutect2, varscan2
- KIF21B | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as rs1320150740; called by muse, mutect2, varscan2
- MAGEC2 | c.828A>C p.K276N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV55997644, COSV99909877; called by muse, mutect2, varscan2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs776720499; called by mutect2, pindel, varscan2
- MSS51 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55019529, COSV55020483; called by muse, mutect2, varscan2
- MUC16 | c.904T>A p.S302T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV67467208; called by muse, varscan2
- NDST4 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs780116580; called by muse, mutect2, varscan2
- NF1 | c.5247A>T p.K1749N (on ENST00000358273 / NM_001042492.3; = p.K1728N on NM_000267.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as CD020581; called by muse, mutect2
- NID1 | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs753021292, COSV99937442; called by muse, mutect2
- NMS | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs547207989, COSV65258502; called by muse, mutect2, varscan2
- OBSL1 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs555893343, COSV54706600; called by muse, mutect2, varscan2
- OLFM1 | c.96A>C p.Q32H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV52963141; called by muse, mutect2, varscan2
- OPN5 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1349834900, COSV55244928; called by muse, mutect2, varscan2
- OR10K2 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59220915; called by muse, mutect2, varscan2
- OR10W1 | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV67721016; called by muse, mutect2, varscan2
- OR10X1 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100936708; called by muse, mutect2, varscan2
- OR13C4 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99470205; called by muse, mutect2, varscan2
- OR2T1 | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63541533; called by muse, mutect2, varscan2
- OR51G2 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV58994284; called by muse, mutect2
- OR52B2 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73209244; called by muse, mutect2, varscan2
- OR8B4 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.081); catalogued as rs748666867; called by muse, varscan2
- P2RY8 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67177262; called by muse, mutect2, varscan2
- PCDHB7 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1554280024, COSV50770160; called by muse, mutect2
- PCDHB7 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50791859; called by muse, mutect2, varscan2
- PDHX | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs765747426; called by muse, mutect2, varscan2
- PKD2 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs529945469; called by muse, mutect2, varscan2
- POSTN | c.1669A>C p.N557H | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65712627; called by muse, mutect2, varscan2
- PRKCSH | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748221415; called by muse, mutect2, varscan2
- RCC1L | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs1365468101; called by muse, mutect2, varscan2
- RNF216 | c.1186G>A p.E396K (on ENST00000425013 / NM_207116.3; = p.E453K on NM_207111.4) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV66289022, COSV66291512; called by muse, mutect2
- SAMD7 | c.1153-1G>C p.X385_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as rs186911150; called by muse, mutect2, varscan2
- SFMBT2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs753989149, COSV62809031; called by muse, mutect2, varscan2
- SVIL | c.4847G>A p.R1616Q (on ENST00000355867 / NM_021738.3; = p.R1190Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV104419700; called by muse, mutect2, varscan2
- THUMPD3 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs191151779; called by muse, mutect2, varscan2
- TMEM132D | c.2594A>G p.K865R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101242707, COSV67158649; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2, varscan2
- TRIM58 | c.498A>C p.K166N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV63572175; called by muse, mutect2
- TRIM58 | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63569272; called by muse, mutect2, varscan2
- ZFHX4 | c.693T>A p.D231E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50483837; called by muse, mutect2
- ZNF208 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.774); catalogued as COSV68110881; called by muse, mutect2, varscan2
- ZNF813 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV67175557; called by muse, mutect2, varscan2
- ZNF878 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.442); catalogued as COSV72156069; called by muse, mutect2
- ABCC12 | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ARHGAP35 | c.1877A>T p.Y626F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ARPP21 | c.12A>T p.Q4H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ATP2C1 | c.2129G>C p.S710T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN10 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- AVPR2 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.023); called by muse, mutect2
- BANK1 | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- BCL11A | c.1388A>G p.E463G (on ENST00000335712 / NM_001365609.1; = p.E497G on NM_018014.4) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- C10orf71 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAND1 | c.3485T>G p.V1162G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC60 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCSAP | c.406_408del p.Q136del | In Frame Del (DEL) | VAF 14/72 reads (19%) | called by pindel, varscan2
- CCT8L2 | c.1571A>G p.K524R | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CFAP47 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 38/55 reads (69%) | called by muse, mutect2, varscan2
- CHL1 | c.2743G>A p.V915I (on ENST00000397491 / NM_001253387.1; = p.V931I on NM_006614.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CNTN4 | c.1400T>G p.V467G | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- COL15A1 | c.3331G>A p.G1111R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COPS5 | c.707A>T p.K236I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); called by muse, mutect2
- CTNND1 | c.2241del p.I747Mfs*10 (on ENST00000399050 / NM_001085458.2; = p.I741Mfs*10 on NM_001331.3) | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel*, varscan2
- CUBN | c.4484A>C p.N1495T | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.071); called by muse, mutect2
- DARS2 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2
- DECR1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DIAPH3 | c.940G>C p.A314P (on ENST00000400324 / NM_001042517.2; = p.A51P on NM_030932.3) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- DNAH11 | c.10636A>C p.T3546P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2
- DOC2A | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- DSEL | c.997T>G p.F333V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- ERV3-1 | c.727A>C p.T243P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- FLT3 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.145); called by muse, mutect2
- FOLH1 | c.2196T>G p.I732M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); called by muse, varscan2
- FOLH1 | c.2124T>G p.I708M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FSTL5 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- GDNF | c.485A>C p.N162T | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GON4L | c.2535G>C p.E845D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- GRIA2 | c.2389G>A p.G797R | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2
- IGHV3-21 | c.143T>C p.F48S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- IKZF1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IL1R1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2
- IRAK4 | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KAZALD1 | c.575_610del p.G192_I203del | In Frame Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel
- KIF4B | c.1868T>G p.L623R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- KIR2DL3 | c.428A>C p.E143A | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KYAT3 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LRP1B | c.4986T>G p.N1662K | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRK2 | c.6965A>G p.K2322R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAGEE1 | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- MTHFD1 | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- MTOR | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- MUC16 | c.29668T>G p.S9890A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- MUC16 | c.23183C>G p.T7728S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NFASC | c.2368C>A p.Q790K (on ENST00000339876 / NM_001378329.1; = p.Q786K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPR2 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NR4A2 | c.1608A>T p.K536N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- OLA1 | c.444A>G p.I148M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10J3 | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR10J5 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10R2 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OR11A1 | c.82T>G p.L28V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- OR11H1 | c.841T>G p.F281V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.24); called by mutect2, varscan2
- OR1L6 | c.133A>T p.S45C (on ENST00000373684; = p.S9C on NM_001004453.2) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR4C11 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- OR51G2 | c.717A>T p.R239S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); called by muse, mutect2
- PADI4 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PCDH15 | c.4289C>A p.A1430E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PCLO | c.4579A>T p.R1527* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- PCNX1 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PDE3A | c.2497G>C p.A833P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEG3 | c.4576A>C p.T1526P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- PLSCR5 | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- PODXL2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.096); called by muse, varscan2
- PPP1R21 | c.895A>C p.K299Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF15 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.203); called by muse, varscan2
- PRAMEF4 | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, varscan2
- PRPF18 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RERGL | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS2 | c.3516A>C p.K1172N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ROBO2 | c.717A>C p.E239D | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SACS | c.6883A>C p.N2295H | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SLC24A5 | c.1483A>C p.I495L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLCO1B3 | c.2075A>C p.N692T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SORCS3 | c.3113G>C p.S1038T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SOX5 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A1 | c.1689A>C p.Q563H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); called by mutect2, varscan2
- SPTA1 | c.6561A>T p.K2187N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SRP19 | c.423_426del p.K142Rfs*37 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by pindel, varscan2
- TFR2 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- TPTE | c.1656A>C p.*552Yext*2 (on ENST00000618007 / NM_199261.4; = p.*534Yext*2 on NM_199259.4) | Nonstop Mutation (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- TRPC7 | c.782A>C p.N261T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TTC16 | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- TTN | c.63787A>C p.T21263P (on ENST00000591111; = p.T13839P on NM_003319.4) | Missense Mutation (SNP) | VAF 22/29 reads (76%) | PolyPhen benign (0.039); called by muse, mutect2, varscan2
- VIP | c.186A>C p.Q62H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ZDBF2 | c.4199A>G p.D1400G | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF225 | c.1972G>C p.G658R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF347 | c.2037A>C p.K679N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF417 | c.941A>T p.H314L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF521 | c.683A>C p.K228T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ZNF577 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF695 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ARHGAP28 | c.690A>G p.K230= (on ENST00000383472 / NM_001366230.1; = p.K71= on NM_001010000.3) | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- BCAN | c.1935C>T p.P645= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs764243051, COSV61257408, COSV61259892; called by muse, mutect2
- CDCP1 | c.675T>G p.S225= | Silent (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- CELF5 | c.840A>T p.I280= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- CFAP69 | c.1020C>A p.A340= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- CLDN17 | c.102T>G p.A34= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV54522992; called by muse, mutect2, varscan2
- DCSTAMP | c.972G>T p.V324= | Silent (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- EPDR1 | c.303A>C p.G101= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV52261803; called by muse, mutect2, varscan2
- FBXO40 | c.1078C>A p.R360= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- FGB | c.426T>G p.S142= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1277349539; called by muse, mutect2, varscan2
- FST | c.675C>T p.C225= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs760808482; called by muse, mutect2, varscan2
- GPR88 | c.168G>A p.V56= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- HSPG2 | c.5592C>T p.S1864= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs376398201, COSV65968788; called by muse, mutect2, varscan2
- IFI44L | c.1248T>C p.I416= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- LCE3A | c.228C>T p.G76= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs112433050; called by muse, mutect2, varscan2
- LRRC30 | c.412T>C p.L138= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV67301493; called by muse, mutect2, varscan2
- MYO1H | c.1815C>T p.N605= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs376635358; called by muse, mutect2, varscan2
- NPLOC4 | c.975C>T p.V325= | Silent (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- OR2D3 | c.327T>G p.S109= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- OR51F1 | c.507T>G p.L169= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- PCOLCE2 | c.240C>T p.L80= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs201403616; called by muse, mutect2, varscan2
- PDCL | c.489G>A p.E163= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1564267960, COSV52342666; called by muse, mutect2, varscan2
- PIAS4 | c.564C>T p.A188= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs201647511, COSV99518546; called by muse, mutect2, varscan2
- PRAMEF15 | c.531A>G p.K177= | Silent (SNP) | VAF 20/214 reads (9%) | called by muse, varscan2
- RELN | c.2323A>C p.R775= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV59019266; called by muse, mutect2, varscan2
- RIMS2 | c.4602T>G p.S1534= (on ENST00000666250 / NM_001348490.2; = p.S1105= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV51717839, COSV51720177, COSV99156042; called by muse, mutect2
- SCGB3A2 | c.240A>G p.E80= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- SYCP2 | c.3429T>G p.T1143= | Silent (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2, varscan2
- TBCE | c.120A>G p.E40= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- TMEM132D | c.1237T>C p.L413= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV70595290, COSV70614870; called by muse, varscan2
- TMEM14C | c.180G>A p.R60= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs1027088153; called by muse, mutect2, varscan2
- TONSL | c.2787G>A p.P929= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs983825450; called by muse, mutect2, varscan2
- TSHZ3 | c.2995T>C p.L999= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- UBQLN3 | c.378A>G p.A126= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- URGCP | c.1011G>A p.L337= (on ENST00000453200 / NM_001077663.3; = p.L328= on NM_017920.4) | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- VWF | c.8025C>T p.F2675= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- VWF | c.4950C>T p.L1650= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2
- WDR37 | c.579C>G p.V193= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- ZBTB7C | c.1374G>A p.T458= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs780087545, COSV59690775; called by muse, mutect2, varscan2
- ZSWIM5 | c.1854G>A p.E618= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- KCNC2 | c.*1912T>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397428 C>T | 3'Flank (SNP) | VAF 19/130 reads (15%) | catalogued as rs1043511186; called by muse, mutect2
- OBSCN | c.11660-2540C>T | Intron (SNP) | VAF 26/90 reads (29%) | catalogued as rs763765287, COSV99475201; called by muse, mutect2, varscan2
- PRR22 | c.194-63C>T | Intron (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- SNORD116-16 | n.78G>A | RNA (SNP) | VAF 12/114 reads (11%) | catalogued as rs537419025; called by muse, mutect2
